Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A1CW, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A1CW-01A (Primary Tumor).

[page 1 of 2]
100-0-3
Carcinoma, papillary follicular variant 8340/3
Site Code: thyroid, NOS 073.9

lw
1/9/11

Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender: F

HCN:

Ordering MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Larynx: mid-line delphian node
2. Thyroid: Total thyroidectomy; stitch right superior pole

Diagnosis

1. No pathological diagnosis: Lymph node (midline delphian) biopsy
2. Multifocal bilateral papillary thyroid carcinoma, dominant 4.5 cm, right; underlying follicular nodular disease: Thyroid, total thyroidectomy specimen.

Prognostic Data

Specimen Type: Other: Total thyroidectomy and delphian node excision biopsy
Tumour Focality: Multifocal
Histologic Type: Dominant Tumour: Papillary carcinoma, follicular variant
Tumour Site: Right Lobe
Tumour Size: Greatest Dimension: 4.5 cm
Additional Dimensions: 2.7 x 2.0 cm
Capsular Invasion: Unencapsulated
Non-invasive
Extrathyroidal Extension: Absent
Margins: Margins uninvolved by carcinoma
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Absent
Histologic Type: Secondary Tumour: Papillary carcinoma, follicular variant
Tumour Site: Isthmus
Tumour Size: Greatest Dimension: 2.2 cm
Additional Dimensions: 1.5 x 1.6 cm
Capsular Invasion: Unencapsulated
Locally invasive
Non-invasive
Extrathyroidal Extension: Absent
Margins: Margins uninvolved by carcinoma
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Absent

Pathologic Staging (pTNM):

pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension (eg, extension to sternothyroid muscle or perithyroid soft tissues)
pN0: No regional lymph node metastasis

Date Reported:	1/9/11	

[page 2 of 2]
Surgical Pathology Consultation Report

Number of regional lymph nodes examined: 1
Number of regional lymph nodes involved: 0

pMX: Distant metastasis cannot be assessed
Nodular hyperplasia

Additional Pathologic Findings: Other (specify): Additional papillary carcinoma, 1.3 cm, left; and multifocal papillary microcarcinoma, bilateral

*Pathologic Staging is based on AJCC/UICC TNM, 6th Edition

Electronically verified by:

Clinical History

thyroid ca.

Gross Description

1. The specimen labeled with the patient's name and as "Larynx: Midline delphian node" consists of a piece of red-tan tissue that measures 0.5 x 0.5 x 0.3 cm.
1A submitted in toto.

2. The specimen labeled with the patient's name and as "Thyroid: Total thyroidectomy; stitch right superior pole" consists of a thyroid gland that is oriented with a stitch and weighs 45.1 g. The right lobe measures 5.3 cm SI x 3.2 cm ML x 2.3 cm AP, the left lobe measures 4.9 cm SI x 2.6 cm ML x 2.3 cm AP and the isthmus measures 4.9 cm SI x 2.1 cm ML x 1.6 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands or lymph nodes are identified grossly. The external surface is painted with silver nitrate. The right lower lobe contains a well delineated nodule that measures 4.5 cm SI x 2.7 cm ML x 2.0 cm AP. The mid left lobe contains a well delineated nodule that measures 3.5 cm SI x 1.5 cm ML x 1.4 cm AP. The isthmus contains a well delineated nodule that measures 2.2 cm SI x 1.5 cm ML x 1.6 cm AP. Sections of the three nodules and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:
2A-J right lobe, superior to inferior
2K-N isthmus
2O-V left lobe, superior to inferior

Source: NCI Genomic Data Commons file 9532c3b3-e17a-4418-8e80-6f4d0e134683 (TCGA-EM-A1CW.7A55B23F-2F3D-4748-9ACD-A947452F787C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).